Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8367, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8367-01A (Primary Tumor).

[page 1 of 3]
		Microscopic Description
	Stomach with a plate-like tumor of 12 x 7 cm in its size, with the whole wall invasion. Fatty tissue lymph nodes are up to 1 cm in their diameter, soft, hyperemic; omentum is hyperemic.	Adenocarcinoma of the stomach, G3; with the presence of signet cells, superficial ulceration, perigastric fat invasion. Multiple foci of perineural invasion are observed. Fifteen lymph nodes were examined, nine lymph nodes demonstrated metastases. Omentum demonstrated hemorrhages.

[page 2 of 3]
Diagnosis Details	Comments	Formatted Path Report
Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:		STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Fundus Tumor size: 7 x 0 x 12 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Subserosa Lymph nodes: 9/15 positive for metastasis (Greater and lesser omentum 9/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 3]
	ID	Excision Date	Laterality

Source: NCI Genomic Data Commons file 69d7b2e1-e47c-49c7-adbe-40fc823a6c4f (TCGA-BR-8367.3ECFC05D-6535-4B71-AD28-6696B9D0995F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).